Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3B1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3B1-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Omentum: omentum
2. Lymph node: Rt. common iliac lymph nodes
3. Lymph node: Rt. pelvic lymph nodes
4. Lymph node: Lt. pelvic lymph node
5. Uterus: Uterus, cervix, bilateral tubes and ovaries
6. Soft Tissue: Right pelvic side wall

Diagnosis

1. Omentum, partial omentectomy:

- Mature adipose tissue, Negative for malignancy.

2. Right common iliac lymph nodes:

- Fibroadipose tissue only.

- No lymphoid tissue present.

3. Right pelvic lymph nodes:

- No tumor seen in four lymph nodes examined.(0/4)

4. Left pelvic lymph nodes:

- No tumor seen in nine lymph nodes examined.(0/9)

5. Uterus, cervix, bilateral fallopian tubes and ovaries, Robotic assisted total hysterectomy and bilateral salpingo-oophorectomy:

Endometrium:

- SEROUS CARCINOMA.

Myometrium:

- Invaded by adenocarcinoma, extending to the outer half of myometrium.

- Leiomyomata and Adenomyosis.

Cervix:

- Negative for malignancy.

Right & left ovaries:

- Negative for malignancy.

Right & left fallopian tubes:

- Negative for malignancy.

Page 1 of 4

ICD-0-3
Carcinoma, serous, NOS 8441/3
Site: Endometrium C54.1 lw
11/13/11

MTAA Discrepancy		X

[page 2 of 4]
Surgical Pathology Consultation Report

6. Soft tissue: right pelvic sidewall:
- Mature adipose tissue, Negative for malignancy.

Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube Omentum
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy Other (specify): robotic-assisted Performed: Pelvic lymph nodes
Lymph Node Sampling:	Intact hysterectomy specimen
Specimen Integrity:	Other: both sides
Tumor Site:	Greatest dimension: 2.9 cm
Tumor Size:	Serous adenocarcinoma
Histologic Type:	Not applicable
Histologic Grade:	Present
Myometrial Invasion:	Myometrial thickness: 1.5 mm 50% or greater myometrial invasion
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Omentum not involved Pelvic wall not involved
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b (IB): Tumor invades more than or one-half of the myometrium
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Pelvic lymph nodes examined: 13 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 0 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Electronically verified by:

Gross Description

[page 3 of 4]
Surgical Pathology Consultation Report

1. The specimen container is labeled with the patient's name and as "Omentum". The specimen consists of 3 un-oriented pieces of lobulated adipose tissue that have an aggregate fresh weight of 48.0 g and measure from 2.9 cm to 8.5 x 7.5 x 1.7 cm. Serial cuts through, and palpation of the specimen show no discrete lesions, firm areas or probable lymph nodes.
1A-1E representative sections

2. The specimen container is labeled with the patient's name and as "Right common iliac lymph nodes". The specimen consists of 2 pieces of fibroadipose tissue that measure, in aggregate, 2.0 x 1.7 x 0.3 cm. No gross lymph nodes are identified within the specimen.

2A submitted in toto

3. The specimen container is labeled with the patient's name and as "Right pelvic lymph nodes". The specimen consists of multiple pieces of fibroadipose tissue that measure, in aggregate, 4.0 x 3.5 x 1.0 cm. Within the tissue pieces are multiple lymph nodes that range from 0.2 to 2.2 cm. Representative sections, lymph nodes submitted in toto:

3A-3B multiple lymph nodes, per block

3C-3D 1 lymph node bisected, per block

4. The specimen container is labeled with the patient's name and as "Left pelvic lymph nodes". The specimen consists of multiple piece of fibroadipose tissue that measure, in aggregate, 6.5 x 4.0 x 1.5 cm. Within the tissue pieces are multiple lymph nodes that range from 0.2 to 2.2 cm. Representative sections, lymph nodes submitted in toto:

4A-4C multiple lymph nodes, per block

4D-4E 1 lymph node bisected, per block

5. The specimen container is labeled with the patient's name and as "Uterus, cervix, bilateral tubes and ovaries". The specimen consists of a total hysterectomy specimen with attached bilateral salpingo-oophorectomy. The specimen has a fresh weight of 71.9 g. The uterus and cervix measures 7.5 cm SI x 5.0 cm ML x 2.9 cm AP. The cervix has a maximum diameter of 2.5 cm. The external os measures 0.7 cm and is oval. The right fallopian tube measures 6.0 x 0.5 cm. The right ovary measures 2.5 x 1.5 x 0.8 cm. The left fallopian tube measures 5.5 x 0.5 cm. The left ovary measures 2.0 by 1.8 x 0.7 cm.

The uterine serosa demonstrates a roughened appearance with fragments of adipose tissue on the fundal aspect. There is a subserosal nodule on the posterior aspect measuring 0.9 cm in diameter. This has a white whorled pattern on cut section. The exocervix is pink-tan and glistening with petechial areas of congestion. The endocervical canal measures 3.5 cm in length. The endometrial cavity measures 3.2 cm SI x 3.0 cm from cornua to cornua. The endometrium demonstrates a papillary tan tumor predominantly inferior aspect that measures 2.4 cm SI by 2.9 cm from cornua to cornua. On the anterior aspect the tumor has a maximum depth of 1.0 cm. It extends into the inner half of the myometrium and comes to within 1.0 cm of the anterior serosa. On the posterior aspect the tumor has a maximum depth of 0.7 cm. It infiltrates the myometrium and comes to within 0.9 cm of the posterior serosa. The myometrium demonstrates 2 white whorled nodules in the posterior aspect measuring 0.9 and 1 cm in diameter. Both fallopian tubes show fimbria. The outer surface of the ovaries is smooth. The cut surface of each ovary demonstrates an unremarkable parenchyma. Multiple pieces of tissue are stored frozen. Representative sections, fimbria and remainder of fallopian tubes and ovaries in toto:

5A-5B anterior cervix to anterior uterine cervical junction, bisected

5C-5D full thickness sections anterior endomyometrium with tumor

5E-5F posterior cervix to posterior uterine cervical junction, bisected

5G posterior subserosal nodule

5H posterior myometrial nodule

5I-5J full thickness sections posterior endomyometrium with tumor

5K right fimbria, longitudinally sectioned

5L-5M right fallopian tube, serially sectioned from fimbrial to cornual end

5N-5P right ovary

5Q left fimbria, longitudinally sectioned

5R-5S left fallopian tube, serially sectioned from fimbrial to cornual end

5T-5U left ovary

6. The specimen container is labeled with the patient's name and as "Of pelvic side wall". The specimen consists of one oriented lobulated piece of adipose tissue measuring 12.5 x 4.5 x 1.0 cm. Serial cuts through and palpation of the tissue demonstrate no discrete lesions or probable lymph nodes.

6A-6E representative sections

[page 4 of 4]
Surgical Pathology Consultation Report

Source: NCI Genomic Data Commons file 69987565-6de6-4e62-9677-369d17f25e9f (TCGA-EO-A3B1.D3309430-5427-4FAD-BDD6-A6E9BABE29D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).